TCGA case TCGA-04-1338 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/31872f6a-d225-4f91-b38d-4505d19e406c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 78 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 78.8 years (28,789 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 1,418 days (3.9 years).
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 0 days; Days to treatment end: 201 days; Number of cycles: 8.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 415 days (1.1 years); Days to treatment end: 510 days (1.4 years); Number of cycles: 6; Treatment dose: 812 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 597 days (1.6 years); Days to treatment end: 627 days (1.7 years); Number of cycles: 1; Treatment dose: 800 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 627 days (1.7 years); Treatment dose: 10 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 79.9 years (29,169 days); Days to diagnosis: 380 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 380 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 380 days (1.0 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,418 days (3.9 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1338-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-04-1338-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 85; Percent necrosis: 15; Percent stromal cells: 30.
  Slide TCGA-04-1338-01A-01-BS1: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 85; Percent necrosis: 15; Percent stromal cells: 40.
- Sample TCGA-04-1338-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 1; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 2: Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxol.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-04-1338-01): tumor purity 0.74, ploidy 2.99, whole-genome doublings 1 (call status: legacy_call).
